Gene-level copy-number profile of tumor specimen TCGA-DU-7290-01A from TCGA case TCGA-DU-7290, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 45.6 years (16,667 days).
Specimen TCGA-DU-7290-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.2914e9de-528e-4f64-b9d5-f5f2c11789a3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DU-7290-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5b261aa0-f080-4c15-ac2f-08717cd34fae

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 7,568; copy number 2: 47,367; copy number 3: 4,852; copy number 4: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-DU-7290-01): tumor purity 0.68, ploidy 1.95, whole-genome doublings 0 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:20,806,292–21,176,888, 1 gene (within-gene range 0–1): EIF4G3.
- chr1:20,988,314–21,485,005, 16 genes (within-gene range 0–2): MIR1256, RPS15AP6, AL627311.1, HSPE1P27, AL031005.2, ECE1, AL031005.1, ECE1-AS1, PPP1R11P1, AL592309.1, AL592309.2, NBPF2P, HS6ST1P1, CROCCP5, NBPF3, PFN1P10.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 7,568. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
